TCGA case TCGA-BC-A8YO — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f53a70d9-a774-4969-896e-2dcdd4d02a7a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Alive.

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 66.2 years (24,189 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 562 days (1.5 years).
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: Yes; Vascular invasion type: Macro.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Sorafenib Tosylate; Days to treatment start: 54 days; Days to treatment end: 186 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 66.8 years (24,409 days); Days to diagnosis: 220 days; Prior treatment: Yes.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease.

Follow-up (3 entries)
- Day 220 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Liver; Days to recurrence: 220 days.
- Days to follow up: 227 days; Disease response: With Tumor.
- Days to follow up: 562 days (1.5 years); Disease response: With Tumor.

Molecular and laboratory tests
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1.
- Creatinine 0.8 mg/dL [Blood test normal range lower: 0.6; Blood test normal range upper: 1].
- Total Bilirubin 0.3 mg/dL [Blood test normal range lower: 0; Blood test normal range upper: 1.2].
- Platelets 441000 (unit not recorded by GDC) [Blood test normal range lower: 150000; Blood test normal range upper: 440000].
- Albumin 4.3 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Alcohol Consumption / Hepatitis, Chronic.
- Timepoint category: Initial Diagnosis; Weight: 74 kg; Height: 170 cm; BMI: 25.6.

Family history
- Relatives with cancer history count: 3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BC-A8YO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 680 mg.
  Slide TCGA-BC-A8YO-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 17; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-BC-A8YO-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BC-A8YO-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Multiple.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment: Pharmaceutical therapy drug name: Nexavar.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 562 days; disease-specific survival: no event (censored), 562 days; disease-free interval: event (new tumor event after initially disease-free), 220 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 220 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BC-A8YO-01A-11D-A36W-01): tumor purity 0.86, ploidy 1.94, whole-genome doublings 0.
